Somatic mutation profile of tumor specimen TCGA-CV-5971-01A (aliquot TCGA-CV-5971-01A-11D-1683-08) from TCGA case TCGA-CV-5971, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 61.0 years (22,279 days).
Specimen TCGA-CV-5971-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f69f14b0-d35f-4bd2-93c6-506e6e6c3f33.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-5971-11A (Solid Tissue Normal), aliquot TCGA-CV-5971-11A-01D-1683-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b417bbb-ec26-425e-9d4d-4ffda7fb9fc0

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 8, Silent 6, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAPK1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 4/54 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519911, COSV53184855, COSV99308005; ClinVar: likely pathogenic; called by muse, mutect2
- FAM189A2 | c.298G>A p.V100I | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as rs534759715, COSV99975133; called by muse, mutect2, varscan2
- FLG | c.1028G>A p.R343K | Missense Mutation (SNP) | VAF 10/273 reads (4%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.812); catalogued as COSV100911659; called by muse, mutect2
- NOTCH1 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1300110216, COSV53032942; called by muse, mutect2
- PATL1 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV100275006; called by muse, mutect2
- PCDHGA3 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 16/177 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV53902230; called by muse, mutect2
- PPP1R26 | c.2671C>T p.R891C | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs753775579, COSV100778043; called by muse, mutect2, varscan2
- SUFU | c.1001G>A p.G334D | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.772); catalogued as COSV100883081; called by muse, mutect2
- KRT5 | c.406_439del p.P136Rfs*4 | Frame Shift Del (DEL) | VAF 8/71 reads (11%) | called by mutect2, pindel
- ATAD2B | c.1992C>T p.S664= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV99477844; called by muse, mutect2
- C3orf38 | c.18C>G p.L6= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as COSV100007417; called by muse, mutect2
- CSNK1G1 | c.480C>A p.L160= | Silent (SNP) | VAF 8/158 reads (5%) | called by muse, mutect2
- FRMPD3 | c.1410G>A p.L470= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as COSV99346484; called by muse, mutect2
- LAMB3 | c.1098G>T p.R366= | Silent (SNP) | VAF 4/68 reads (6%) | catalogued as COSV100620388; called by muse, mutect2
- TAS2R5 | c.444C>T p.F148= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV99924810; called by muse, mutect2
